Somatic mutation profile of tumor specimen ALCH-B5VP-TTP1-A (aliquot ALCH-B5VP-TTP1-A-1-0-D-A87U-36) from ALCHEMIST case ALCH-B5VP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,455 days).
Specimen ALCH-B5VP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33ea209f-da6e-4ea9-b807-b90d089a0b34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5VP-NB1-A (Blood Derived Normal), aliquot ALCH-B5VP-NB1-A-2-0-D-A87U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa3210ea-0b53-40a7-8b7d-c45d3797334a

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.8288A>T p.D2763V | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV56405558; called by muse, mutect2
- DAPK1 | c.602+5G>C | Splice Region (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- ROBO1 | c.2442+1G>T p.X814_splice | Splice Site (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- SORCS1 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
